Gene-level copy-number profile of tumor specimen 1105219 from CPTAC case C846363, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105219: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd4cff1f-a062-44b0-bfdc-9b688f6efecc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105216 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/aecd3a66-486d-40bd-96fb-beea4df3c4ad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 4; copy number 2: 9,293; copy number 3: 16,332; copy number 4: 30,113; copy number 5: 105; copy number 6: 153; copy number 7: 61; copy number 8: 1,806; copy number 9: 976; copy number 10: 12; copy number 82: 5; copy number 84: 1; copy number 94: 3; copy number 167: 6.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,209,189–22,455,740, 43 genes: IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,003 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:4,775,615–4,959,213, 8 genes, copy number 10: AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2.
- chr7:54,556,970–55,572,988, 15 genes, copy number 82–167 (within-gene range 6–167): VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:62,275,361–67,362,950, 193 genes, copy number 9–10 (broad region; genes not listed).
- chr7:72,829,425–95,615,132, 374 genes, copy number 9 (broad region; genes not listed).
- chr7:104,738,597–104,804,107, 1 gene, copy number 9 (within-gene range 8–9): LHFPL3-AS1.
- chr7:104,894,628–131,496,632, 412 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
